Gene-level copy-number profile of tumor specimen TCGA-D1-A1NX-01A from TCGA case TCGA-D1-A1NX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.9 years (24,441 days).
Specimen TCGA-D1-A1NX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.36253961-4505-4fa9-ae57-96162540c7e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A1NX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a77e0dce-1ed8-4977-99a5-d4c245d21dab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 9,566; copy number 2: 44,248; copy number 3: 5,379; copy number 4: 514; copy number 5: 32; copy number 6: 56; copy number 12: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A1NX-01A-11D-A16C-01): tumor purity 0.88, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 102 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:13,549,125–13,746,638, 2 genes, copy number 5 (within-gene range 2–5): FBLN2, LINC00620.
- chr4:1,550,284–2,069,089, 16 genes, copy number 6: AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L.
- chr4:2,088,718–2,090,617, 1 gene, copy number 6: AL136360.1.
- chr10:59,955,430–59,960,913, 1 gene, copy number 5: LINC01553.
- chr10:60,050,668–60,060,743, 1 gene, copy number 5: AL592430.1.
- chr10:93,306,429–93,604,480, 5 genes, copy number 5 (within-gene range 3–5): MYOF, CEP55, RNA5SP323, FFAR4, RBP4.
- chr10:100,912,963–101,137,789, 14 genes, copy number 5 (within-gene range 3–5): SLF2, AL133215.3, MRPL43, SEMA4G, MIR608, AL133215.1, TWNK, LZTS2, PDZD7, SFXN3, AL133215.2, KAZALD1, TLX1NB, TLX1.
- chr12:564,296–911,452, 9 genes, copy number 5 (within-gene range 3–5): NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1.
- chr17:39,546,104–39,864,312, 14 genes, copy number 12 (within-gene range 2–12): RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr19:58,326,994–58,605,223, 39 genes, copy number 6 (within-gene range 4–6): ZSCAN22, A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1.

Autosomal genes at a single copy (total copy number 1): 7,159. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
